CPTAC case C3N-02429 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/98c51a04-d042-47a0-aeeb-f62e4f1eebac

Demographics
Sex at birth: male; Race: asian; Year of birth: 1975; Vital status: Alive; Country of birth: China.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 41.7 years (15,227 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T1a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Tumor grade: G3; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,782 days (4.9 years); Progression or recurrence: no; Days to last follow up: 1,782 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 351 days; Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 734 days (2.0 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,063 days (2.9 years); Disease response: Complete Response; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,063 days (2.9 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,453 days (4.0 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 1,782 days (4.9 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.

Other clinical attributes
- Weight: 80 kg; Height: 172 cm; BMI: 27.04.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02429-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 100 mg; Time between clamping and freezing: 15 minutes; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02429-21: Section location: right upper pole; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3N-02429-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 100 mg; Time between clamping and freezing: 15 minutes; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02429-22: Section location: right upper pole; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3N-02429-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 100 mg; Time between clamping and freezing: 15 minutes; Time between excision and freezing: 7 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-02429-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -3 days; Method of sample procurement: Blood Draw.
